MMRF case MMRF_1159 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f56298dc-d136-4676-9a11-d171d9cf52d8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.6 years (27,596 days); ISS stage: III; Days to last known disease status: 1,736 days (4.8 years); Days to last follow up: 1,736 days (4.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 3.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 43.1 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 8.27 µg/mL; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 20.3 mmol/L; Calcium 1.88 mmol/L; Albumin 31 g/L; Total Protein 8.8 g/dL; Glucose 9.96 mmol/L.
- Day 92 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.6 g/dL; Glucose 7.1 mmol/L.
- Day 165: M Protein 1.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.91 µg/mL; Lactate Dehydrogenase 8.65 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 8.03 mmol/L.
- Day 269 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 6.66 mmol/L.
- Day 372 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 6.52 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 7.21 mmol/L.
- Day 470 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.859 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 4.8 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.82 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 8.09 mmol/L.
- Day 525 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.77 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 116 ×10⁹/L.
- Day 589 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 1.17 g/L; Lactate Dehydrogenase 6.73 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 10.1 mmol/L.
- Day 729 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 7.07 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 1.51 g/L; Lactate Dehydrogenase 6.88 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 9.19 mmol/L.
- Day 792 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 7.94 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 1.23 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 9.85 mmol/L.
- Day 883 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 6.82 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 1.15 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 7.92 mmol/L.
- Day 976 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 1.32 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 12.5 mmol/L.
- Day 1,068 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 6.4 g/dL; Glucose 6.88 mmol/L.
- Day 1,173 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 5.87 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 1.28 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 6.71 mmol/L.
- Day 1,243 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 6.18 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 1.45 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 7.43 mmol/L.
- Day 1,365 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 1.43 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 10.3 mmol/L.
- Day 1,491 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 6.93 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 1.57 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 5.6 g/dL; Glucose 10.7 mmol/L.
- Day 1,610 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.38 mg/dL; Immunoglobulin G 6.44 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 1.58 g/L; Lactate Dehydrogenase 6.87 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 4.57 mmol/L.
- Day 1,736 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 1.48 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 7.26 mmol/L.

Other clinical attributes
- Day -6: Weight: 121 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample MMRF_1159_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
